CPTAC case C3N-02186 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ddaeb900-6184-4341-b060-0fdc6f505dd9

Demographics
Sex at birth: male; Race: asian; Year of birth: 1964; Vital status: Alive; Country of birth: China.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 53.5 years (19,526 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 264 days; Progression or recurrence: yes; Days to recurrence: 99 days; Days to last follow up: 264 days.
   Pathology details: Greatest tumor dimension: 6.5 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 264 days; Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 264 days; Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 99 days; Karnofsky performance status: 80; ECOG performance status: 1.

Other clinical attributes
- Weight: 67 kg; Height: 175 cm; BMI: 21.88.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (10 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Samples C3N-02186-01, C3N-02186-02 (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 500 mg.
- Sample C3N-02186-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -1 day; Initial weight: 500 mg; Time between excision and freezing: 7 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02186-23: Section location: Right Hemisphere; Percent tumor nuclei: 75; Percent necrosis: 5.
- Samples C3N-02186-31, C3N-02186-32, C3N-02186-72, C3N-02186-73, C3N-02186-74, C3N-02186-75 (6 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-02186-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -1 day; Method of sample procurement: Blood Draw.
